Somatic mutation profile of tumor specimen ALCH-B4CV-TTP1-A (aliquot ALCH-B4CV-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B4CV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.8 years (21,098 days).
Specimen ALCH-B4CV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b86650be-a90b-485c-91ff-55009544395c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4CV-NB1-A (Blood Derived Normal), aliquot ALCH-B4CV-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/675dca5a-16f5-4c00-85ff-a738fc3ed645

The open-access MAF lists 264 somatic variants for this specimen: 186 protein-altering or splice-affecting, 51 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 51, Intron 16, Nonsense Mutation 11, Splice Site 6, RNA 4, 5'UTR 4, Splice Region 3, 3'UTR 3, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 96/720 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 22/200 reads (11%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 43/305 reads (14%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- AMY2B | c.929T>C p.F310S | Missense Mutation (SNP) | VAF 138/1216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279419248; called by muse, mutect2, varscan2
- BRCA1 | c.4603G>C p.E1535Q | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); catalogued as CM014692; called by muse, mutect2, varscan2
- C11orf49 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.914); catalogued as rs141798325; called by muse, mutect2, varscan2
- C16orf96 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71471793; called by muse, mutect2, varscan2
- CBY2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1176194494, COSV60117334; called by muse, mutect2, varscan2
- CC2D2B | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 58/610 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as rs768630692, COSV100729592; called by muse, mutect2, varscan2
- CCDC151 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1245640216; called by muse, mutect2
- CDKL4 | c.874G>C p.A292P | Missense Mutation (SNP) | VAF 30/329 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as COSV101115281; called by muse, mutect2
- CNTNAP5 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs1379804148; called by muse, mutect2
- COL11A1 | c.2755-1G>T p.X919_splice | Splice Site (SNP) | VAF 86/946 reads (9%) | catalogued as COSV62176070; called by muse, mutect2
- COL25A1 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 52/712 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs1467292578; called by muse, mutect2
- CROCC2 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs1254943218; called by muse, mutect2
- CSMD2 | c.522C>A p.H174Q | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV53912233, COSV53919670; called by muse, mutect2, varscan2
- DACH2 | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV64162750, COSV64170787; called by muse, mutect2, varscan2
- DCBLD1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 110/1114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51647306; called by muse, mutect2, varscan2
- DPP8 | c.547G>T p.G183C (on ENST00000341861 / NM_001320875.2; = p.G167C on NM_017743.6) | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as COSV55682468; called by muse, mutect2, varscan2
- EMCN | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104400163; called by muse, mutect2, varscan2
- EPHA10 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs964464777; called by muse, mutect2
- FAM135B | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs187739434, COSV52708604; called by muse, mutect2, varscan2
- FTH1 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 112/900 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs1416394825; called by muse, varscan2
- GP1BA | c.301T>C p.S101P | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as rs780294091; called by muse, mutect2, varscan2
- GXYLT2 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.179); catalogued as rs1236741876; called by muse, varscan2
- KCNJ3 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV54547753; called by muse, mutect2, varscan2
- KEAP1 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV50260883; called by muse, mutect2, varscan2
- KIF2B | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52128924; called by muse, mutect2
- KLHL29 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99942995; called by muse, mutect2, varscan2
- LRIF1 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.875); catalogued as rs1030734128; called by muse, mutect2, varscan2
- LYPD6 | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV61940086; called by muse, mutect2
- MYH2 | c.2070G>T p.M690I | Missense Mutation (SNP) | VAF 161/1229 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV55449554; called by muse, mutect2, varscan2
- NECAB2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 24/185 reads (13%) | catalogued as COSV59420016; called by muse, mutect2, varscan2
- NOTCH1 | c.4870G>T p.E1624* | Nonsense Mutation (SNP) | VAF 19/137 reads (14%) | catalogued as COSV53034838, COSV53071099; called by muse, mutect2, varscan2
- NRXN1 | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV58502276; called by muse, varscan2
- OR2G3 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1334372032; called by muse, mutect2, varscan2
- P4HA2 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51331272; called by muse, mutect2, varscan2
- PCDH15 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 65/1009 reads (6%) | catalogued as COSV100226388; called by muse, mutect2
- PCDHGA12 | c.2080G>T p.V694L | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV52761740; called by muse, mutect2
- PCDHGA8 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV53956333; called by muse, mutect2, varscan2
- PPP1R16B | c.1397C>T p.T466I | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs567999418; called by muse, mutect2, varscan2
- PRTG | c.3283C>A p.P1095T | Missense Mutation (SNP) | VAF 91/722 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.343); catalogued as COSV66838253; called by muse, mutect2, varscan2
- PSMC6 | c.854A>C p.H285P (on ENST00000612399; = p.H271P on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV101471179; called by muse, mutect2, varscan2
- PTPRD | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 48/420 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.375); catalogued as rs1294518613, COSV61958412; called by muse, mutect2, varscan2
- PTPRS | c.5485C>T p.R1829W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs147647579; called by muse, mutect2, varscan2
- RGS14 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 41/360 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.481); catalogued as rs780154954, COSV68771398; called by muse, mutect2, varscan2
- SALL1 | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs769014673, COSV51755641; called by muse, mutect2
- SORCS3 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs530482370; called by muse, mutect2
- SPX | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 103/666 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs750496888, COSV57020031; called by muse, mutect2, varscan2
- STC1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 62/536 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143373578; called by muse, mutect2, varscan2
- TEX15 | c.1805T>C p.I602T (on ENST00000256246; = p.I985T on NM_001350162.2) | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1279084397; called by muse, mutect2
- TGIF2LX | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 137/581 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV52215080, COSV52215374, COSV99383415; called by muse, mutect2, varscan2
- XIRP2 | c.8371G>A p.A2791T (on ENST00000628543; = p.A2966T on NM_152381.6) | Missense Mutation (SNP) | VAF 19/274 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV54684317, COSV54704132; called by muse, mutect2
- ZNF230 | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 58/630 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV71273465; called by muse, mutect2
- ZNF568 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 56/453 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1038787887; called by muse, mutect2, varscan2
- ZNF835 | c.583C>G p.R195G | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV73379397; called by muse, mutect2
- ABCA13 | c.44A>T p.N15I | Missense Mutation (SNP) | VAF 58/474 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ABCB5 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- AKAP13 | c.7646A>T p.Q2549L (on ENST00000394518 / NM_007200.5; = p.Q2553L on NM_006738.6) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ALDH7A1 | c.1473G>C p.E491D | Missense Mutation (SNP) | VAF 74/1051 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANGPT4 | c.1152C>A p.D384E | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANO4 | c.2168C>A p.T723K (on ENST00000392977 / NM_001286615.2; = p.T688K on NM_178826.4) | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ASIC5 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 117/926 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ATAD2B | c.1564C>A p.H522N | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ATAD5 | c.2118G>C p.L706F | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATRN | c.2805G>C p.L935F | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ATRN | c.3970G>C p.A1324P | Missense Mutation (SNP) | VAF 75/541 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BAP1 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 87/508 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- BBS7 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 71/1098 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BEST1 | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 123/644 reads (19%) | called by muse, mutect2, varscan2
- BPHL | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- C2CD4B | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C7orf26 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CABIN1 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 58/522 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPRIN2 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 52/450 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC151 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, mutect2
- CDC42BPB | c.4011G>C p.K1337N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CIITA | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CNTN6 | c.1125G>T p.M375I | Missense Mutation (SNP) | VAF 50/528 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- COBLL1 | c.35C>G p.S12C (on ENST00000392717; = p.S20C on NM_001278458.2) | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL7A1 | c.5708C>A p.P1903H | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPO | c.484-1G>A p.X162_splice | Splice Site (SNP) | VAF 59/339 reads (17%) | called by muse, mutect2, varscan2
- CTNND2 | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- DAPK1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- DHRS1 | c.686C>G p.T229R | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); called by muse, mutect2
- DIPK2B | c.586A>T p.S196C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.7439C>T p.T2480I | Missense Mutation (SNP) | VAF 115/591 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- DMGDH | c.259G>C p.G87R | Missense Mutation (SNP) | VAF 58/590 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH2 | c.10077C>A p.C3359* | Nonsense Mutation (SNP) | VAF 31/313 reads (10%) | called by muse, mutect2
- DPP10 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 110/793 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EIF4G1 | c.3954-1G>A p.X1318_splice (on ENST00000346169 / NM_198241.3; = p.X1123_splice on NM_004953.5) | Splice Site (SNP) | VAF 82/429 reads (19%) | called by muse, mutect2, varscan2
- ERP29 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- EVL | c.1088+8A>G | Splice Region (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- FANCI | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 66/707 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.106); called by muse, mutect2
- FTH1 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 202/1134 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, varscan2
- FTMT | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 30/606 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- GABRG1 | c.1253G>C p.C418S | Missense Mutation (SNP) | VAF 150/1480 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- GPRC5C | c.694G>T p.G232C (on ENST00000652232; = p.G187C on NM_018653.4) | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GREB1 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HFM1 | c.3248G>T p.G1083V | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIVEP2 | c.3398A>G p.E1133G | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HOXA11 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL31RA | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 62/663 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- ISL2 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ITGA11 | c.1625T>C p.F542S | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNH7 | c.1279T>A p.Y427N | Missense Mutation (SNP) | VAF 144/1200 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- KDM6B | c.1269C>G p.D423E | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- KDR | c.3084C>A p.D1028E | Missense Mutation (SNP) | VAF 76/760 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLF11 | c.42+1G>T p.X14_splice | Splice Site (SNP) | VAF 29/249 reads (12%) | called by muse, mutect2, varscan2
- KLHDC3 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- KYNU | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 59/434 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LAMA4 | c.3320T>A p.L1107Q (on ENST00000230538 / NM_001105206.3; = p.L1100Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/879 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LGI1 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 46/612 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2
- LGI1 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 47/605 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2
- LINGO2 | c.1601T>C p.F534S | Missense Mutation (SNP) | VAF 62/530 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- LPA | c.3488C>G p.P1163R | Missense Mutation (SNP) | VAF 55/702 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEC2 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAL | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMEL1 | c.1551G>T p.E517D | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC17 | c.3472G>T p.G1158* | Nonsense Mutation (SNP) | VAF 42/489 reads (9%) | called by muse, mutect2
- MYPN | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 75/672 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NCOA2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 80/844 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NDST2 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NIPAL4 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 102/1246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NMNAT2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH2 | c.5525C>G p.S1842* | Nonsense Mutation (SNP) | VAF 67/419 reads (16%) | called by muse, mutect2, varscan2
- NR2F2 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2
- OR10AG1 | c.777A>T p.Q259H | Missense Mutation (SNP) | VAF 80/918 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2
- OR11L1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 28/313 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- OR1D2 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 106/892 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- OR2T8 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6K2 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8I2 | c.419T>A p.V140E | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- OR9Q1 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDH15 | c.3452G>C p.G1151A | Missense Mutation (SNP) | VAF 42/616 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH9 | c.2513G>T p.C838F | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PLA2G5 | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- PRKCZ | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PRKRIP1 | c.126G>T p.P42= | Splice Region (SNP) | VAF 30/281 reads (11%) | called by muse, mutect2, varscan2
- PTGER4 | c.1384A>G p.R462G | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTH2R | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 75/609 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTHLH | c.101+2T>C p.X34_splice | Splice Site (SNP) | VAF 45/206 reads (22%) | called by muse, mutect2, varscan2
- PTPN21 | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 67/689 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- QRICH2 | c.1666C>A p.Q556K | Missense Mutation (SNP) | VAF 69/504 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBM10 | c.2246G>T p.R749L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- REC8 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RGR | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 48/559 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- RPL4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 40/424 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2
- SAMD11 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- SBF2 | c.3422C>T p.T1141I | Missense Mutation (SNP) | VAF 115/697 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SCYL2 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.281); called by muse, varscan2
- SDK1 | c.2630A>T p.Q877L | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SDK1 | c.3071A>G p.N1024S | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC31A | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 42/454 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.221); called by muse, mutect2
- SLC16A10 | c.206G>T p.W69L | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.386); called by muse, varscan2
- SLIT1 | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SPECC1 | c.1676A>G p.Q559R | Missense Mutation (SNP) | VAF 62/437 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SRCIN1 | c.2482G>T p.E828* (on ENST00000621492; = p.E794* on NM_025248.3) | Nonsense Mutation (SNP) | VAF 42/346 reads (12%) | called by muse, mutect2, varscan2
- SYMPK | c.3133A>G p.T1045A | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); called by muse, mutect2
- SYT4 | c.1226G>T p.C409F | Missense Mutation (SNP) | VAF 77/584 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYT6 | c.1424del p.G475Afs*25 (on ENST00000610222 / NM_001366225.1; = p.G390Afs*25 on NM_205848.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/377 reads (11%) | called by mutect2, pindel, varscan2
- TAT | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 58/696 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TCF20 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.069); called by muse, varscan2
- TET1 | c.1736T>C p.L579S | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.307); called by muse, mutect2
- THUMPD2 | c.751-8T>A | Splice Region (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- TIAM1 | c.809A>T p.H270L | Missense Mutation (SNP) | VAF 80/525 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TIMD4 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 40/629 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.215); called by muse, mutect2
- TLE3 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAV8-6 | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2
- TRIOBP | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 104/803 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TTN | c.10006C>A p.P3336T (on ENST00000591111; = p.P3290T on NM_003319.4) | Missense Mutation (SNP) | VAF 86/1293 reads (7%) | PolyPhen benign (0.043); called by muse, mutect2
- TUBA3C | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2
- UBQLNL | c.928C>G p.P310A | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UFD1 | c.352C>G p.Q118E | Missense Mutation (SNP) | VAF 58/466 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB7C | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZC3H3 | c.1784G>T p.W595L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFAND1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.158); called by muse, mutect2
- ZFP36L1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF16 | c.1018C>G p.Q340E | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- ZNF197 | c.2608G>T p.G870* | Nonsense Mutation (SNP) | VAF 47/285 reads (16%) | called by muse, mutect2, varscan2
- ZNF354B | c.1358T>G p.L453R | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF407 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF438 | c.1423A>T p.T475S | Missense Mutation (SNP) | VAF 55/534 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF525 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 31/364 reads (9%) | called by muse, mutect2
- ZNF534 | c.1632C>A p.F544L (on ENST00000332323 / NM_001143939.3; = p.F531L on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZNF557 | c.613G>C p.D205H (on ENST00000414706 / NM_001044388.2; = p.D212H on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.234); called by muse, mutect2
- ABI3BP | c.2745C>T p.V915= | Silent (SNP) | VAF 118/1006 reads (12%) | called by muse, mutect2, varscan2
- AC100868.1 | c.12T>A p.G4= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- ANKFN1 | c.2085T>C p.N695= | Silent (SNP) | VAF 52/383 reads (14%) | called by muse, mutect2, varscan2
- ATP11A | c.1758G>C p.V586= | Silent (SNP) | VAF 51/440 reads (12%) | called by muse, mutect2, varscan2
- BBS7 | c.126G>T p.G42= | Silent (SNP) | VAF 68/1094 reads (6%) | called by muse, mutect2
- BTN3A3 | c.1323G>A p.K441= | Silent (SNP) | VAF 38/361 reads (11%) | catalogued as rs748007508; called by muse, mutect2, varscan2
- C12orf50 | c.636C>A p.V212= | Silent (SNP) | VAF 54/543 reads (10%) | called by muse, mutect2, varscan2
- CFAP43 | c.4098C>T p.D1366= | Silent (SNP) | VAF 81/701 reads (12%) | called by muse, mutect2, varscan2
- CIC | c.4665G>T p.G1555= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- DCC | c.495G>T p.G165= | Silent (SNP) | VAF 128/1215 reads (11%) | called by muse, mutect2
- DLK2 | c.888G>A p.R296= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- EPB41L3 | c.3054C>T p.T1018= | Silent (SNP) | VAF 26/253 reads (10%) | called by muse, mutect2
- ERICH3 | c.2853A>T p.I951= | Silent (SNP) | VAF 37/337 reads (11%) | called by muse, mutect2, varscan2
- EYS | c.2751A>G p.R917= | Silent (SNP) | VAF 48/373 reads (13%) | called by muse, mutect2, varscan2
- FAM135B | c.3501T>A p.P1167= | Silent (SNP) | VAF 28/360 reads (8%) | catalogued as COSV52723926; called by muse, mutect2
- FKBP1C | c.51G>A p.P17= | Silent (SNP) | VAF 35/327 reads (11%) | catalogued as rs184619290, COSV62178957; called by muse, mutect2, varscan2
- FLT1 | c.2331C>A p.T777= | Silent (SNP) | VAF 66/654 reads (10%) | catalogued as rs1262616956; called by muse, mutect2
- FUT2 | c.711C>A p.L237= | Silent (SNP) | VAF 61/356 reads (17%) | catalogued as COSV67179104; called by muse, mutect2, varscan2
- GGCX | c.1062G>A p.Q354= | Silent (SNP) | VAF 23/201 reads (11%) | catalogued as rs1168438689; called by muse, mutect2, varscan2
- GRHL2 | c.201C>T p.L67= | Silent (SNP) | VAF 30/231 reads (13%) | catalogued as COSV52555514; called by muse, mutect2, varscan2
- GRIA4 | c.2685T>A p.A895= | Silent (SNP) | VAF 48/335 reads (14%) | called by muse, mutect2, varscan2
- GRK2 | c.384C>T p.A128= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV57953574; called by muse, mutect2, varscan2
- GSS | c.204G>A p.V68= | Silent (SNP) | VAF 33/255 reads (13%) | called by muse, mutect2, varscan2
- HK3 | c.495C>T p.F165= | Silent (SNP) | VAF 23/266 reads (9%) | catalogued as rs1177043626; called by muse, mutect2
- KCNU1 | c.849A>G p.V283= | Silent (SNP) | VAF 95/836 reads (11%) | called by muse, mutect2, varscan2
- KCNU1 | c.1428T>G p.A476= | Silent (SNP) | VAF 75/759 reads (10%) | called by muse, mutect2
- KIF26B | c.843C>T p.S281= | Silent (SNP) | VAF 36/384 reads (9%) | catalogued as rs370325336; called by muse, mutect2
- MPDZ | c.4590G>T p.L1530= | Silent (SNP) | VAF 28/241 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.29409A>T p.T9803= | Silent (SNP) | VAF 15/220 reads (7%) | called by muse, mutect2
- MYO15B | c.2499G>A p.L833= | Silent (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- NUP160 | c.3210T>C p.A1070= | Silent (SNP) | VAF 41/292 reads (14%) | catalogued as COSV65855749; called by muse, mutect2, varscan2
- OR4C46 | c.183G>T p.L61= | Silent (SNP) | VAF 92/702 reads (13%) | called by muse, mutect2, varscan2
- OR5B3 | c.417T>C p.C139= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2
- PIK3R1 | c.1785C>T p.N595= (on ENST00000521381 / NM_181523.3; = p.N325= on NM_181504.4) | Silent (SNP) | VAF 127/1004 reads (13%) | catalogued as rs760360348, COSV99140999; called by muse, mutect2, varscan2
- POLR1E | c.723G>A p.K241= (on ENST00000377792 / NM_001282766.1; = p.K179= on NM_022490.4) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1051597714; called by muse, mutect2, varscan2
- PRKAG3 | c.96A>G p.E32= | Silent (SNP) | VAF 26/596 reads (4%) | catalogued as rs1179162465; called by muse, mutect2
- RYR1 | c.4287C>T p.T1429= | Silent (SNP) | VAF 22/291 reads (8%) | catalogued as rs1020726350; ClinVar: likely benign; called by muse, mutect2
- SENP7 | c.1365A>G p.S455= | Silent (SNP) | VAF 59/528 reads (11%) | called by muse, mutect2, varscan2
- SEPHS1 | c.1167G>T p.G389= | Silent (SNP) | VAF 56/449 reads (12%) | called by muse, mutect2, varscan2
- SH3D21 | c.1494A>G p.R498= (on ENST00000453908 / NM_001162530.2; = p.R387= on NM_024676.5) | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- SLC22A3 | c.1101A>C p.G367= | Silent (SNP) | VAF 104/1054 reads (10%) | called by muse, mutect2
- SLC5A8 | c.555T>C p.V185= | Silent (SNP) | VAF 38/390 reads (10%) | called by muse, mutect2
- SMAD6 | c.636C>T p.D212= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs575612166; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTB | c.651C>A p.P217= | Silent (SNP) | VAF 101/571 reads (18%) | called by muse, mutect2, varscan2
- TMEM132D | c.1404G>A p.E468= | Silent (SNP) | VAF 30/356 reads (8%) | called by muse, mutect2
- TMPRSS4 | c.213C>T p.I71= | Silent (SNP) | VAF 28/243 reads (12%) | catalogued as rs749801075; called by muse, mutect2, varscan2
- TMTC1 | c.1059G>A p.R353= (on ENST00000539277 / NM_001193451.2; = p.R245= on NM_175861.3) | Silent (SNP) | VAF 38/323 reads (12%) | called by muse, mutect2, varscan2
- TNFSF14 | c.288G>T p.A96= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV55591597; called by muse, mutect2, varscan2
- WDR44 | c.1743C>T p.C581= | Silent (SNP) | VAF 56/160 reads (35%) | called by muse, mutect2, varscan2
- ZNF415 | c.216A>C p.T72= | Silent (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- ZXDA | c.486G>T p.A162= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- AC004696.1 | n.2C>T | RNA (SNP) | VAF 38/366 reads (10%) | called by muse, mutect2, varscan2
- AMD1 | c.428-13C>G | Intron (SNP) | VAF 47/516 reads (9%) | called by muse, mutect2
- ATRNL1 | c.3795+48165C>A | Intron (SNP) | VAF 69/557 reads (12%) | called by muse, mutect2, varscan2
- CCDC28B | c.548+97C>A | Intron (SNP) | VAF 51/436 reads (12%) | called by muse, mutect2, varscan2
- CHORDC1 | c.329+607G>T | Intron (SNP) | VAF 20/223 reads (9%) | catalogued as rs1348542240; called by muse, mutect2
- CPT1C | c.1731+91G>T | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- CSGALNACT1 | c.*190A>T | 3'UTR (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- CTSH | c.-22G>C | 5'UTR (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- FUBP1 | c.1927-11C>G | Intron (SNP) | VAF 52/604 reads (9%) | called by muse, mutect2
- GATAD2A | c.-90-1068G>T | Intron (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8237del | Intron (DEL) | VAF 31/278 reads (11%) | called by mutect2, pindel, varscan2
- GCOM1 | c.1305-2775G>T | Intron (SNP) | VAF 48/349 reads (14%) | called by muse, mutect2, varscan2
- HAL | c.855+37C>G | Intron (SNP) | VAF 50/592 reads (8%) | catalogued as rs1357007136; called by muse, mutect2
- HERC2 | c.13273-24G>T | Intron (SNP) | VAF 59/439 reads (13%) | called by muse, mutect2, varscan2
- HNF4A | c.1129+47A>T | Intron (SNP) | VAF 33/221 reads (15%) | catalogued as COSV57387730; called by muse, mutect2, varscan2
- LINC00303 | n.790C>A | RNA (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- LY6E | c.-16G>T | 5'UTR (SNP) | VAF 12/95 reads (13%) | catalogued as rs1166525802; called by muse, mutect2, varscan2
- MIR518B | n.13C>A | RNA (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2
- NT5DC3 | c.-56C>G | 5'UTR (SNP) | VAF 24/123 reads (20%) | catalogued as rs932148339; called by muse, mutect2, varscan2
- PAFAH1B2 | c.-48A>G | 5'UTR (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- QRFPR | c.499+31T>A | Intron (SNP) | VAF 41/333 reads (12%) | called by muse, mutect2, varscan2
- RBISP1 | n.77A>G | RNA (SNP) | VAF 15/173 reads (9%) | called by muse, mutect2
- RNF207 | c.628-35C>T | Intron (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- TRIO | c.*1002C>T | 3'UTR (SNP) | VAF 31/246 reads (13%) | called by muse, mutect2, varscan2
- UQCRB | c.*1782A>T | 3'UTR (SNP) | VAF 101/998 reads (10%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+43791G>T | Intron (SNP) | VAF 60/566 reads (11%) | called by muse, mutect2, varscan2
- ZFAND1 | c.636+28A>G | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
